Somatic mutation profile of tumor specimen TCGA-13-0904-01A (aliquot TCGA-13-0904-01A-02W-0420-08) from TCGA case TCGA-13-0904, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 63.7 years (23,278 days).
Specimen TCGA-13-0904-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7077a22d-f7f0-40c7-812e-e234f5416bef.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-13-0904-10A (Blood Derived Normal), aliquot TCGA-13-0904-10A-01D-0399-01; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0c4d2efd-e161-4bb6-9c90-4f71626527cb

The open-access MAF lists 138 somatic variants for this specimen: 99 protein-altering or splice-affecting, 38 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 81, Silent 38, Frame Shift Del 6, Nonsense Mutation 6, Splice Site 3, Frame Shift Ins 2, Intron 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.836G>A p.G279E | Missense Mutation (SNP) | VAF 175/202 reads (87%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1064793881, COSV52677880, COSV52851240; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACVR1 | c.206G>T p.G69V | Missense Mutation (SNP) | VAF 80/428 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55119983; called by muse, mutect2, varscan2
- ADGRE5 | c.842A>T p.K281I (on ENST00000242786 / NM_078481.4; = p.K188I on NM_001784.5) | Missense Mutation (SNP) | VAF 45/164 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.065); catalogued as COSV54412361; called by muse, mutect2, varscan2
- ADGRG4 | c.1613C>G p.P538R | Missense Mutation (SNP) | VAF 283/738 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.69); catalogued as COSV54960021; called by muse, mutect2, varscan2
- ANKRD30A | c.1021T>A p.C341S (on ENST00000611781; = p.C285S on NM_052997.2) | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.879); catalogued as COSV64613679; called by muse, mutect2, varscan2
- AP2A1 | c.536C>T p.S179L | Missense Mutation (SNP) | VAF 38/112 reads (34%) | SIFT tolerated (0.64); PolyPhen probably damaging (1); catalogued as rs759251973, COSV62818448; called by muse, mutect2, varscan2
- ARHGAP32 | c.5356G>T p.G1786W (on ENST00000310343 / NM_001378025.1; = p.G1437W on NM_014715.4) | Missense Mutation (SNP) | VAF 62/884 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV100087254, COSV59856390; called by muse, mutect2
- ARHGEF4 | c.480C>A p.S160R | Missense Mutation (SNP) | VAF 34/65 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV58124623; called by muse, mutect2, varscan2
- ATP10D | c.2102A>T p.D701V | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.079); catalogued as COSV56709164; called by muse, mutect2, varscan2
- ATP8A2 | c.1497G>T p.E499D | Missense Mutation (SNP) | VAF 170/390 reads (44%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.98); catalogued as COSV54960429; called by muse, mutect2, varscan2
- BCHE | c.932G>T p.G311V | Missense Mutation (SNP) | VAF 49/169 reads (29%) | SIFT tolerated (0.28); PolyPhen benign (0.015); catalogued as COSV52258414; called by muse, mutect2, varscan2
- BMP3 | c.578A>G p.D193G | Missense Mutation (SNP) | VAF 89/209 reads (43%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.937); catalogued as rs763285730, COSV51087618; called by muse, mutect2, varscan2
- BTBD8 | c.408G>T p.K136N | Missense Mutation (SNP) | VAF 12/21 reads (57%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as COSV61546831; called by muse, mutect2, varscan2
- BUD31 | c.7A>G p.K3E | Missense Mutation (SNP) | VAF 58/294 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.79); catalogued as COSV56117484; called by muse, mutect2, varscan2
- CA5A | c.750G>T p.E250D | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.042); catalogued as COSV59241552; called by muse, mutect2, varscan2
- CARMIL2 | c.1126G>C p.G376R | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as COSV58028373; called by muse, mutect2, varscan2
- CCBE1 | c.787C>A p.P263T | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.922); catalogued as COSV67950364; called by muse, mutect2, varscan2
- CDNF | c.503T>C p.V168A | Missense Mutation (SNP) | VAF 61/293 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs374288522; called by muse, mutect2, varscan2
- CEP192 | c.3695C>G p.T1232R | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT tolerated (0.35); PolyPhen benign (0.005); catalogued as COSV58066552; called by muse, mutect2, varscan2
- CERS3 | c.340G>T p.E114* | Nonsense Mutation (SNP) | VAF 20/100 reads (20%) | catalogued as COSV52570352; called by muse, mutect2, varscan2
- CLEC4F | c.290A>G p.E97G | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV55480076; called by muse, mutect2, varscan2
- CPE | c.896C>A p.P299Q | Missense Mutation (SNP) | VAF 72/406 reads (18%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.938); catalogued as COSV68581152; called by muse, mutect2, varscan2
- CPN2 | c.649G>T p.G217C | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.09); PolyPhen benign (0.062); catalogued as COSV60470817; called by muse, mutect2, varscan2
- DAGLB | c.1820+2T>C p.X607_splice | Splice Site (SNP) | VAF 3/15 reads (20%) | catalogued as COSV51705061; called by muse, mutect2
- DCHS1 | c.3565C>A p.P1189T | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV55038006; called by muse, mutect2, varscan2
- DDB2 | c.1012A>C p.T338P | Missense Mutation (SNP) | VAF 88/439 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV57039414; called by muse, mutect2, varscan2
- DNAH10 | c.3029A>G p.E1010G (on ENST00000409039; = p.E949G on NM_207437.3) | Missense Mutation (SNP) | VAF 6/86 reads (7%) | SIFT tolerated (0.19); PolyPhen benign (0.019); catalogued as COSV69002012; called by muse, mutect2
- DNAH5 | c.9733G>A p.V3245M | Missense Mutation (SNP) | VAF 85/512 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54234866; called by muse, varscan2
- EHD2 | c.112G>T p.E38* | Nonsense Mutation (SNP) | VAF 9/27 reads (33%) | catalogued as COSV54409353; called by muse, mutect2, varscan2
- ELOVL3 | c.754C>A p.H252N | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV64174625; called by muse, mutect2, varscan2
- FHDC1 | c.628C>G p.R210G | Missense Mutation (SNP) | VAF 42/49 reads (86%) | SIFT deleterious (0.05); PolyPhen benign (0.29); catalogued as COSV52600936; called by muse, mutect2, varscan2
- GIMAP1 | c.851dup p.A285Rfs*22 | Frame Shift Ins (INS) | VAF 5/46 reads (11%) | catalogued as rs756722011; called by pindel, varscan2
- GRK1 | c.820G>T p.D274Y | Missense Mutation (SNP) | VAF 82/273 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59553269; called by muse, mutect2, varscan2
- HDAC6 | c.439C>T p.L147= | Splice Region (SNP) | VAF 209/778 reads (27%) | catalogued as COSV61929505; called by muse, mutect2, varscan2
- HECW1 | c.2575C>G p.R859G | Missense Mutation (SNP) | VAF 42/145 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV67832892; called by muse, mutect2, varscan2
- HTR3C | c.269G>A p.W90* | Nonsense Mutation (SNP) | VAF 59/209 reads (28%) | catalogued as rs1264025455; called by muse, mutect2, varscan2
- IGDCC4 | c.467A>T p.E156V | Missense Mutation (SNP) | VAF 33/88 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.026); catalogued as rs770329652, COSV61537793; called by muse, mutect2, varscan2
- IQCC | c.911A>T p.D304V | Missense Mutation (SNP) | VAF 13/79 reads (16%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV52209622; called by muse, mutect2, varscan2
- ISG20L2 | c.974T>C p.V325A | Missense Mutation (SNP) | VAF 58/325 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57460598; called by muse, mutect2, varscan2
- JAKMIP2 | c.102G>C p.Q34H | Missense Mutation (SNP) | VAF 113/1148 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV54608050; called by muse, mutect2
- KAT6A | c.1367A>G p.N456S | Missense Mutation (SNP) | VAF 127/434 reads (29%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.985); catalogued as rs925201894, COSV55907837; called by muse, mutect2, varscan2
- KCNH7 | c.2483T>A p.L828H | Missense Mutation (SNP) | VAF 29/167 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59801380; called by muse, mutect2, varscan2
- KDM4D | c.868G>A p.A290T | Missense Mutation (SNP) | VAF 178/764 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782787300, COSV58634581; called by muse, varscan2
- KIAA1210 | c.535G>A p.E179K | Missense Mutation (SNP) | VAF 161/364 reads (44%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV68178223; called by muse, mutect2, varscan2
- KIF25 | c.9G>T p.W3C | Missense Mutation (SNP) | VAF 32/196 reads (16%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.022); catalogued as COSV63027098, COSV63027810; called by muse, varscan2
- LRIG2 | c.3186T>G p.S1062R | Missense Mutation (SNP) | VAF 44/206 reads (21%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as COSV63162210, COSV63162786; called by muse, mutect2, varscan2
- LRP5 | c.3281A>G p.E1094G | Missense Mutation (SNP) | VAF 22/132 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.797); catalogued as COSV53718199; called by muse, mutect2, varscan2
- MAP7D1 | c.2385G>C p.Q795H | Missense Mutation (SNP) | VAF 27/207 reads (13%) | SIFT tolerated (0.38); PolyPhen benign (0.063); catalogued as COSV60217022; called by muse, mutect2, varscan2
- MEMO1 | c.431T>A p.M144K | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54453857; called by muse, mutect2
- MGAT5B | c.203G>A p.R68H | Missense Mutation (SNP) | VAF 51/200 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs776468880, COSV56931355; called by muse, mutect2, varscan2
- MMP15 | c.1420C>T p.P474S | Missense Mutation (SNP) | VAF 31/45 reads (69%) | SIFT deleterious (0.04); PolyPhen benign (0.351); catalogued as COSV54680361; called by muse, mutect2, varscan2
- MMP2 | c.1198G>C p.V400L | Missense Mutation (SNP) | VAF 91/183 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV54602745; called by muse, mutect2, varscan2
- MMRN1 | c.190G>T p.E64* | Nonsense Mutation (SNP) | VAF 27/96 reads (28%) | catalogued as COSV53338655; called by muse, mutect2, varscan2
- MYH7B | c.3712G>C p.A1238P | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as COSV52681355, COSV52681649; called by muse, varscan2
- NAAA | c.223T>C p.W75R | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.271); catalogued as COSV99715810; called by mutect2, varscan2
- NCOA3 | c.1696G>T p.D566Y | Missense Mutation (SNP) | VAF 124/451 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV59070182; called by muse, mutect2, varscan2
- P4HA3 | c.577G>A p.D193N | Missense Mutation (SNP) | VAF 78/727 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0.031); catalogued as COSV100525626; called by muse, mutect2, varscan2
- PCNX4 | c.2923G>C p.V975L (on ENST00000406854 / NM_001330177.2; = p.V741L on NM_022495.5) | Missense Mutation (SNP) | VAF 61/149 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.077); catalogued as COSV58302605, COSV58305408; called by muse, mutect2, varscan2
- PLCB3 | c.1004A>G p.Y335C | Missense Mutation (SNP) | VAF 205/220 reads (93%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99657232; called by muse, mutect2, varscan2
- PPEF2 | c.1131C>A p.C377* | Nonsense Mutation (SNP) | VAF 14/92 reads (15%) | catalogued as COSV54423635, COSV54427201; called by muse, varscan2
- PPP1R7 | c.772T>C p.Y258H | Missense Mutation (SNP) | VAF 26/36 reads (72%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV52145613; called by muse, mutect2, varscan2
- PRKAA2 | c.219T>A p.H73Q | Missense Mutation (SNP) | VAF 53/162 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV64804560; called by muse, mutect2, varscan2
- PRUNE2 | c.5199G>C p.K1733N | Missense Mutation (SNP) | VAF 135/326 reads (41%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV65043234; called by muse, mutect2, varscan2
- PTPN18 | c.430T>C p.Y144H | Missense Mutation (SNP) | VAF 107/418 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51559475; called by muse, mutect2, varscan2
- RELN | c.10044C>G p.D3348E | Missense Mutation (SNP) | VAF 114/791 reads (14%) | SIFT tolerated (0.61); PolyPhen benign (0.04); catalogued as COSV59012341; called by muse, mutect2, varscan2
- RLIM | c.350G>T p.R117I | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV60327411; called by muse, mutect2, varscan2
- RNF115 | c.452G>A p.G151E | Missense Mutation (SNP) | VAF 27/135 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.643); catalogued as COSV65165009; called by muse, mutect2, varscan2
- SACS | c.5069T>A p.V1690E | Missense Mutation (SNP) | VAF 42/101 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV66542442; called by muse, mutect2, varscan2
- SAMD3 | c.830C>T p.A277V | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs768973043, COSV63717525; called by muse, mutect2, varscan2
- SCN11A | c.3470C>T p.A1157V | Missense Mutation (SNP) | VAF 148/667 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1359085925, COSV56566871; called by muse, mutect2, varscan2
- SCN9A | c.1095C>G p.N365K | Missense Mutation (SNP) | VAF 107/484 reads (22%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.981); catalogued as COSV57614251; called by muse, mutect2, varscan2
- SERPINB5 | c.919A>T p.M307L | Missense Mutation (SNP) | VAF 126/512 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV66975682; called by muse, mutect2, varscan2
- SHQ1 | c.592C>A p.H198N | Missense Mutation (SNP) | VAF 25/122 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV57766359; called by muse, mutect2, varscan2
- SIGLEC1 | c.3508+1G>T p.X1170_splice | Splice Site (SNP) | VAF 22/71 reads (31%) | catalogued as COSV52466387; called by muse, mutect2, varscan2
- SLC18A3 | c.1543C>G p.P515A | Missense Mutation (SNP) | VAF 51/165 reads (31%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV60327477; called by muse, mutect2, varscan2
- SLC22A15 | c.323C>A p.S108Y | Missense Mutation (SNP) | VAF 28/200 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); catalogued as COSV65678493; called by muse, mutect2, varscan2
- SPTB | c.2182C>G p.L728V | Missense Mutation (SNP) | VAF 135/294 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV67632890; called by muse, mutect2, varscan2
- STARD8 | c.1368C>A p.N456K | Missense Mutation (SNP) | VAF 28/61 reads (46%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.601); catalogued as COSV52928347; called by muse, mutect2, varscan2
- TENM1 | c.6773C>T p.A2258V | Missense Mutation (SNP) | VAF 491/928 reads (53%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.647); catalogued as rs372260419, COSV64428572; called by muse, mutect2, varscan2
- TNIP3 | c.643C>T p.R215* | Nonsense Mutation (SNP) | VAF 15/36 reads (42%) | catalogued as rs778852023, COSV50249949; called by muse, mutect2, varscan2
- TTN | c.26858A>G p.N8953S (on ENST00000591111; = p.N8026S on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 141/577 reads (24%) | PolyPhen benign (0); catalogued as rs763189626, COSV60152987; called by muse, mutect2, varscan2
- UCHL5 | c.223G>C p.D75H | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.151); catalogued as rs778080751, COSV66486684; called by muse, mutect2, varscan2
- USH2A | c.8485G>T p.V2829L | Missense Mutation (SNP) | VAF 61/188 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.066); catalogued as COSV56390494; called by muse, mutect2, varscan2
- USP14 | c.723T>G p.S241R | Missense Mutation (SNP) | VAF 56/166 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.114); catalogued as COSV55281751; called by muse, mutect2, varscan2
- USP49 | c.1486C>T p.L496F | Missense Mutation (SNP) | VAF 13/65 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51894733, COSV51898521; called by muse, mutect2, varscan2
- WDSUB1 | c.491C>T p.T164I | Missense Mutation (SNP) | VAF 8/101 reads (8%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.963); catalogued as rs1192685295; called by muse, mutect2
- ZG16B | c.457T>C p.S153P | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT deleterious (0.01); PolyPhen benign (0.069); catalogued as COSV66525971; called by muse, mutect2, varscan2
- CAMTA1 | c.4688_4689+32del p.X1563_splice | Splice Site (DEL) | VAF 26/184 reads (14%) | called by mutect2, pindel
- CDRT1 | c.480T>A p.F160L | Missense Mutation (SNP) | VAF 20/59 reads (34%) | SIFT tolerated (0.6); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- COL1A1 | c.149G>A p.R50Q | Missense Mutation (SNP) | VAF 50/1604 reads (3%) | SIFT tolerated (0.07); PolyPhen benign (0.001); called by muse, mutect2
- HNF1B | c.1168_1178del p.D390Qfs*6 | Frame Shift Del (DEL) | VAF 284/367 reads (77%) | called by mutect2, pindel, varscan2
- IGHV3-48 | c.243C>A p.D81E | Missense Mutation (SNP) | VAF 126/504 reads (25%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- MOGAT3 | c.533_558del p.L178Rfs*50 | Frame Shift Del (DEL) | VAF 33/133 reads (25%) | called by mutect2, pindel, varscan2
- OR6K6 | c.837del p.F279Lfs*9 (on ENST00000368144; = p.F255Lfs*9 on NM_001005184.1) | Frame Shift Del (DEL) | VAF 20/119 reads (17%) | called by mutect2, pindel, varscan2
- OR9A2 | c.20G>C p.S7T | Missense Mutation (SNP) | VAF 91/456 reads (20%) | SIFT tolerated (0.65); PolyPhen benign (0.445); called by muse, mutect2, varscan2
- RAP1GAP | c.944_948dup p.Y317Mfs*52 | Frame Shift Ins (INS) | VAF 92/425 reads (22%) | called by mutect2, pindel, varscan2
- SCN7A | c.1442del p.T481Ifs*3 | Frame Shift Del (DEL) | VAF 10/51 reads (20%) | called by mutect2, pindel, varscan2
- SMOC2 | c.586del p.L196Ffs*41 (on ENST00000356284 / NM_001166412.2; = p.L207Ffs*41 on NM_022138.3) | Frame Shift Del (DEL) | VAF 39/220 reads (18%) | called by mutect2, pindel, varscan2
- VBP1 | c.426_427del p.L143Vfs*13 | Frame Shift Del (DEL) | VAF 39/193 reads (20%) | called by mutect2, pindel, varscan2
- ADGRB1 | c.4419G>T p.R1473= | Silent (SNP) | VAF 7/66 reads (11%) | catalogued as rs1342260468, COSV60099012; called by muse, mutect2, varscan2
- C12orf66 | c.276C>T p.T92= | Silent (SNP) | VAF 32/56 reads (57%) | catalogued as COSV61323711; called by muse, mutect2, varscan2
- C3orf20 | c.84C>A p.L28= | Silent (SNP) | VAF 43/156 reads (28%) | catalogued as rs1431806520, COSV53783097, COSV53786519; called by muse, mutect2, varscan2
- CARMIL3 | c.2547C>G p.L849= | Silent (SNP) | VAF 80/304 reads (26%) | catalogued as COSV57727054; called by muse, mutect2, varscan2
- CEMIP2 | c.3756G>A p.P1252= | Silent (SNP) | VAF 93/215 reads (43%) | catalogued as rs748073493, COSV65487975; called by muse, mutect2, varscan2
- CNBD1 | c.1287A>G p.E429= | Silent (SNP) | VAF 14/31 reads (45%) | catalogued as COSV73073890; called by muse, mutect2, varscan2
- COL26A1 | c.81C>T p.F27= | Silent (SNP) | VAF 12/17 reads (71%) | catalogued as rs1433496391, COSV58126915; called by muse, mutect2
- DGKE | c.66G>C p.L22= | Silent (SNP) | VAF 26/76 reads (34%) | catalogued as COSV52350290; called by muse, mutect2, varscan2
- DNAH5 | c.9852G>T p.L3284= | Silent (SNP) | VAF 112/602 reads (19%) | catalogued as COSV54234538; called by muse, varscan2
- FANCG | c.1101C>T p.Y367= | Silent (SNP) | VAF 119/302 reads (39%) | catalogued as COSV62721077; called by muse, mutect2, varscan2
- FPR2 | c.486C>G p.L162= | Silent (SNP) | VAF 65/254 reads (26%) | catalogued as COSV60673296; called by muse, mutect2, varscan2
- GRIK2 | c.1230C>G p.G410= | Silent (SNP) | VAF 33/155 reads (21%) | catalogued as COSV59745865; called by muse, mutect2, varscan2
- GRIN2B | c.4128G>C p.S1376= | Silent (SNP) | VAF 19/360 reads (5%) | catalogued as COSV101662967; called by muse, mutect2
- HDAC6 | c.1522T>C p.L508= | Silent (SNP) | VAF 113/355 reads (32%) | catalogued as COSV61929509; called by muse, mutect2, varscan2
- KCND2 | c.702G>T p.T234= | Silent (SNP) | VAF 33/122 reads (27%) | catalogued as COSV58587393; called by muse, mutect2, varscan2
- KRT26 | c.708T>G p.A236= | Silent (SNP) | VAF 43/113 reads (38%) | called by muse, mutect2, varscan2
- KRT6C | c.1300C>T p.L434= | Silent (SNP) | VAF 77/187 reads (41%) | catalogued as rs1374895879, COSV52878444; called by muse, mutect2, varscan2
- MMRN1 | c.3432A>G p.V1144= | Silent (SNP) | VAF 15/71 reads (21%) | catalogued as COSV53339004; called by muse, mutect2, varscan2
- MUC17 | c.7638G>A p.V2546= | Silent (SNP) | VAF 84/503 reads (17%) | catalogued as COSV60293124; called by muse, mutect2, varscan2
- MUC4 | c.2172G>C p.L724= | Silent (SNP) | VAF 15/59 reads (25%) | called by muse, mutect2, varscan2
- MYO18B | c.2208C>T p.L736= | Silent (SNP) | VAF 22/69 reads (32%) | catalogued as COSV59138765; called by muse, mutect2, varscan2
- MYOZ1 | c.648C>A p.P216= | Silent (SNP) | VAF 89/471 reads (19%) | catalogued as COSV63772152; called by muse, mutect2, varscan2
- PIGZ | c.15A>T p.G5= | Silent (SNP) | VAF 36/108 reads (33%) | catalogued as COSV53013999; called by muse, mutect2, varscan2
- PKHD1L1 | c.12180T>A p.I4060= | Silent (SNP) | VAF 49/99 reads (49%) | catalogued as rs777071568; called by muse, mutect2, varscan2
- PRAG1 | c.2271C>T p.T757= | Silent (SNP) | VAF 45/213 reads (21%) | catalogued as rs56187292, COSV58160147; called by muse, mutect2, varscan2
- PTPN21 | c.2907C>G p.A969= | Silent (SNP) | VAF 80/243 reads (33%) | catalogued as COSV60849432; called by muse, mutect2, varscan2
- SEMA5A | c.498G>A p.Q166= | Silent (SNP) | VAF 123/216 reads (57%) | catalogued as COSV66797343; called by muse, mutect2, varscan2
- SIGLEC1 | c.4287C>T p.N1429= | Silent (SNP) | VAF 40/211 reads (19%) | catalogued as COSV52466382; called by muse, mutect2, varscan2
- SNRNP200 | c.2370C>A p.T790= | Silent (SNP) | VAF 147/813 reads (18%) | catalogued as COSV60491300; called by muse, mutect2, varscan2
- SPRR2E | c.120G>A p.K40= | Silent (SNP) | VAF 141/729 reads (19%) | catalogued as COSV64203838, COSV64203849; called by muse, mutect2, varscan2
- SUPT3H | c.432A>G p.R144= (on ENST00000371460 / NM_181356.3; = p.R133= on NM_003599.4 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 43/117 reads (37%) | catalogued as COSV60942686; called by muse, mutect2, varscan2
- TLN1 | c.456G>T p.L152= | Silent (SNP) | VAF 475/1798 reads (26%) | catalogued as COSV59208874; called by muse, mutect2, varscan2
- UNC45B | c.781C>A p.R261= | Silent (SNP) | VAF 40/106 reads (38%) | catalogued as COSV52093620, COSV52097330; called by muse, mutect2, varscan2
- UNC45B | c.2541C>A p.T847= | Silent (SNP) | VAF 64/146 reads (44%) | catalogued as rs201746299, COSV52097341; called by muse, mutect2, varscan2
- VWF | c.858C>T p.T286= | Silent (SNP) | VAF 76/237 reads (32%) | catalogued as rs776206258, COSV54616799; ClinVar: likely benign / uncertain significance; called by muse, mutect2, varscan2
- WDFY3 | c.5685G>T p.L1895= | Silent (SNP) | VAF 188/739 reads (25%) | catalogued as COSV99882608; called by muse, mutect2, varscan2
- WDFY3 | c.4102T>C p.L1368= | Silent (SNP) | VAF 137/367 reads (37%) | catalogued as rs1178843277, COSV99882613; called by muse, mutect2, varscan2
- ZNF133 | c.1573C>A p.R525= (on ENST00000316358 / NM_001352454.2; = p.R524= on NM_003434.7 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 110/474 reads (23%) | catalogued as COSV60366866, COSV60367405; called by muse, varscan2
- BNIP1 | c.178-2631_178-2626del | Intron (DEL) | VAF 24/70 reads (34%) | called by mutect2, pindel, varscan2
